Gene-level copy-number profile of tumor specimen ALCH-AEFM-TTP1-A from ALCHEMIST case ALCH-AEFM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,826 days).
Specimen ALCH-AEFM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file caf8ffc9-8645-4c66-8ea5-fd7bfb8f9c7f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEFM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/135f0e77-d75a-48f0-9007-154bf91ee7ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 10,467; copy number 2: 41,654; copy number 3: 5,564; copy number 4: 224; copy number 5: 246; copy number 6: 162; copy number 8: 5; copy number 9: 13; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,555,793–228,619,350, 7 genes: RNA5SP19, RNA5SP162, RNA5S1, RNA5S2, RNA5S3, RNA5S4, RNA5S5.
- chr9:85,159,682–85,159,950, 1 gene: UBE2V1P10.
- chr14:99,481,169–99,535,044, 1 gene (within-gene range 0–2): CCNK.
- chr14:99,512,501–99,513,576, 1 gene (within-gene range 0–2): AL110504.1.
- chr15:25,182,385–25,220,578, 21 genes (within-gene range 0–1): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:85,180,200–85,234,795, 1 gene (within-gene range 0–2): AC044860.1.
- chr15:85,191,438–85,247,170, 3 genes: CSPG4P12, RN7SL428P, GOLGA6L3.
- chr16:2,464,950–2,509,560, 4 genes (within-gene range 0–3): AC106820.2, NTN3, TBC1D24, AC106820.4.
- chr16:69,975,238–69,975,344, 1 gene: AC026468.1.
- chr17:15,732,247–15,749,315, 3 genes (within-gene range 0–2): TBC1D26, TBC1D26-AS1, AC005324.5.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–3): BCRP6, FAM230H, AP000552.2.
- chr22:29,720,003–29,767,011, 3 genes (within-gene range 0–2): CABP7, ZMAT5, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 427 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,248,691–20,352,234, 1 gene, copy number 5: PUM2.
- chr3:147,939,905–148,591,927, 10 genes, copy number 6: AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1.
- chr3:166,160,021–170,418,615, 74 genes, copy number 5–8 (broad region; genes not listed).
- chr3:170,459,548–170,586,075, 2 genes, copy number 8 (within-gene range 1–8): SLC7A14, KRT8P13.
- chr3:171,600,404–172,711,218, 17 genes, copy number 5–6 (within-gene range 4–6): PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2.
- chr3:172,711,151–172,725,038, 1 gene, copy number 6: AC108667.2.
- chr12:46,004,038–47,236,662, 19 genes, copy number 6–9: AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1.
- chr12:48,995,149–50,480,004, 69 genes, copy number 5 (broad region; genes not listed).
- chr12:50,763,710–51,515,763, 30 genes, copy number 5–6: ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1.
- chr12:52,314,301–52,473,805, 11 genes, copy number 5: KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C.
- chr12:52,948,871–53,677,408, 44 genes, copy number 5–9 (within-gene range 2–9): KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, MFSD5, ESPL1, PFDN5, AC073611.1, MYG1-AS1, MYG1, AAAS, SP7, SP1, AMHR2, PRR13, AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1.
- chr12:62,260,338–63,272,336, 24 genes, copy number 5 (within-gene range 1–5): USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69.
- chr12:63,804,739–65,248,355, 48 genes, copy number 6 (within-gene range 2–6): RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:66,347,431–69,823,204, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:78,674,048–78,782,297, 1 gene, copy number 5 (within-gene range 2–5): CYTH1.
- chr17:78,696,694–78,696,797, 1 gene, copy number 5: RNU6-638P.
- chr22:21,341,595–21,345,258, 1 gene, copy number 6: PPP1R26P5.
- chr22:21,370,064–21,371,945, 1 gene, copy number 13: AP000552.1.
- chr22:21,466,423–21,471,269, 1 gene, copy number 5: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 10,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
